Somatic mutation profile of tumor specimen TCGA-06-0145-01A (aliquot TCGA-06-0145-01A-01W-0224-08) from TCGA case TCGA-06-0145, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.8 years (19,661 days).
Specimen TCGA-06-0145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0a198bf-acf9-4e0f-9114-617c4acd5a9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0145-10A (Blood Derived Normal), aliquot TCGA-06-0145-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54904499-a62d-4501-a4ea-044340a35284

The open-access MAF lists 110 somatic variants for this specimen: 79 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 26, Nonsense Mutation 4, Frame Shift Del 3, Intron 3, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs863223696, CM1512505, COSV61340800, COSV61349273; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ADCY10 | c.4517G>A p.G1506D | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1558137342; called by muse, mutect2
- CAMTA1 | c.4066C>T p.R1356W | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs777480195, COSV57916271; called by muse, mutect2, varscan2
- CHEK1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs778046191, COSV54024890; called by muse, mutect2, varscan2
- CNKSR2 | c.2930A>G p.D977G | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs773692431, COSV65279966; called by muse, mutect2, varscan2
- CORO1C | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54596356; called by muse, mutect2
- DISP1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV52662554; called by muse, mutect2, varscan2
- DMD | c.6482C>T p.T2161I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV58933192; called by muse, varscan2
- DMXL1 | c.1607C>T p.T536I | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as rs759353166; called by muse, mutect2, varscan2
- DOCK8 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs375686155, COSV66633902; called by muse, mutect2, varscan2
- EYA2 | c.1458G>C p.R486S | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57948112, COSV57949476; called by muse, mutect2, varscan2
- FAT2 | c.6350G>A p.R2117Q | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.933); catalogued as rs763727182, COSV55825497; called by muse, mutect2, varscan2
- GABRA1 | c.809T>C p.V270A | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV50112403; called by muse, mutect2, varscan2
- GABRE | c.564-2A>T p.X188_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV64819707; called by muse, mutect2, varscan2
- GPR143 | c.729del p.I244Sfs*10 | Frame Shift Del (DEL) | VAF 90/230 reads (39%) | catalogued as COSV66632850; called by mutect2, pindel, varscan2
- GRHL3 | c.497C>T p.P166L (on ENST00000350501 / NM_198174.3; = p.P171L on NM_021180.3) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.702); catalogued as COSV52569372; called by mutect2, varscan2
- HYDIN | c.3688C>A p.Q1230K | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.42); catalogued as COSV66833527; called by muse, mutect2, varscan2
- KCNQ5 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 48/592 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); catalogued as rs771263285, COSV59658299; called by muse, mutect2
- KEL | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs374644780, COSV62336671; called by muse, mutect2, varscan2
- KMT2C | c.4906A>C p.T1636P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs80039782; called by muse, mutect2
- LAMA2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV70352351; called by muse, mutect2, varscan2
- LRFN5 | c.846T>A p.F282L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV53268171; called by muse, mutect2, varscan2
- LUM | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1565758968, COSV57128773; called by muse, mutect2, varscan2
- MCOLN3 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.271); catalogued as rs144793042; called by muse, mutect2, varscan2
- MCTP1 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV56527994; called by muse, mutect2
- MYCT1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs375330501; called by muse, mutect2, varscan2
- NEDD4 | c.2131G>C p.D711H (on ENST00000508342 / NM_001284338.1; = p.D292H on NM_006154.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1327002172, COSV59063520; called by mutect2, varscan2
- NLRP2 | c.2715G>A p.W905* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99672548; called by muse, mutect2, varscan2
- OR51S1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs143553379, COSV59057098; called by muse, mutect2
- OR5D18 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV61738076; called by muse, mutect2, varscan2
- P2RY4 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65736964; called by muse, mutect2, varscan2
- PADI3 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs200183399, COSV64934955; called by muse, mutect2, varscan2
- PAN3 | c.1539A>T p.K513N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56705947; called by muse, mutect2, varscan2
- PPFIBP1 | c.2398G>A p.A800T (on ENST00000318304 / NM_177444.3; = p.A794T on NM_003622.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs376329180; called by muse, mutect2, varscan2
- PRDM10 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs777711002; called by mutect2, varscan2
- PSG4 | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV54938329; called by muse, mutect2, varscan2
- RGL1 | c.2194A>T p.K732* (on ENST00000360851 / NM_001297672.2; = p.K767* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/168 reads (22%) | catalogued as COSV58991031; called by muse, mutect2, varscan2
- RUNX2 | c.1205C>T p.P402L (on ENST00000371438; = p.P380L on NM_001015051.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs770452837, CD104813, COSV100767761, COSV61844036; called by muse, mutect2
- SCML2 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52623764; called by muse, mutect2, varscan2
- SPAG5 | c.1016G>A p.W339* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as rs1358140256; called by muse, mutect2
- SS18 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV52262795; called by muse, mutect2, varscan2
- ST6GAL1 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 56/151 reads (37%) | PolyPhen probably damaging (0.991); catalogued as rs750933745, COSV51472774; called by muse, mutect2, varscan2
- TENM1 | c.3422A>G p.H1141R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64438406; called by muse, mutect2, varscan2
- TKTL2 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180820487, COSV54922318; called by muse, mutect2, varscan2
- TRPA1 | c.2978G>T p.W993L | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV51563874, COSV51569055; called by muse, mutect2, varscan2
- UGT2A1 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs767856867, COSV54142254; called by muse, mutect2, varscan2
- XIRP2 | c.3136A>G p.K1046E (on ENST00000628543; = p.K1221E on NM_152381.6) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV54701070; called by muse, mutect2, varscan2
- ZNF521 | c.53A>G p.K18R | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.034); catalogued as COSV64129816; called by muse, mutect2, varscan2
- ZNF808 | c.1181G>T p.S394I | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1392633417; called by muse, mutect2
- ZPBP | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs200427468; called by muse, mutect2, varscan2
- ACTN1 | c.2462C>A p.A821D | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2
- ANGEL2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- ARMT1 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ATP6V0A1 | c.1639C>T p.H547Y | Missense Mutation (SNP) | VAF 479/1012 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, varscan2
- BAZ2B | c.4789C>T p.P1597S | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.96); called by muse, varscan2
- C1QTNF7 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, varscan2
- CENPF | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CX3CR1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- GFI1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | called by muse, varscan2
- HSPA4L | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.055); called by muse, mutect2
- JADE1 | c.1940del p.Q647Rfs*6 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, varscan2
- KIAA1109 | c.8704C>T p.P2902S | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MASP1 | c.1284C>A p.S428R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2
- MDM1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2
- MYO1E | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NHLRC2 | c.1753G>T p.V585L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- OR52N5 | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI4 | c.1192del p.T398Qfs*15 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel, varscan2
- PELI1 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- POLR2A | c.2815G>A p.V939M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.602); called by muse, mutect2
- PRDM15 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PROS1 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SCO1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TPM1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTC21B | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.345); called by muse, mutect2
- TTF2 | c.3442G>A p.V1148I | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.112); called by muse, mutect2
- UBASH3A | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UHRF1BP1L | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- WDR89 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADCY1 | c.1707C>T p.I569= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- AP002748.5 | c.1677G>A p.L559= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CFAP221 | c.1614C>T p.F538= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs369030643; called by muse, mutect2, varscan2
- COL28A1 | c.2634C>T p.A878= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1379465770; called by muse, mutect2, varscan2
- CPOX | c.615G>A p.V205= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs962573015; called by muse, mutect2, varscan2
- DIAPH2 | c.756A>G p.G252= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV61283305; called by muse, mutect2, varscan2
- FKBP11 | c.504C>T p.L168= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- FOXN1 | c.736C>T p.L246= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- GRM1 | c.2346C>T p.N782= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs145874853; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDC | c.432C>T p.G144= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs757801293, COSV51068448; called by muse, mutect2, varscan2
- KCND2 | c.1620C>T p.I540= | Silent (SNP) | VAF 6/119 reads (5%) | called by muse, mutect2
- KIAA1217 | c.5757C>T p.P1919= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- LGI1 | c.1596G>A p.K532= | Silent (SNP) | VAF 24/126 reads (19%) | catalogued as rs763321683; called by muse, mutect2, varscan2
- MS4A7 | c.117C>T p.N39= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs767560560, COSV55729105; called by muse, mutect2, varscan2
- NDRG2 | c.525C>T p.A175= (on ENST00000298687 / NM_001354570.1; = p.A161= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- NLRP8 | c.288C>T p.R96= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs146471073; called by muse, mutect2, varscan2
- OR2G2 | c.285C>T p.I95= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV60740233, COSV60742244; called by muse, mutect2, varscan2
- PATJ | c.1827C>T p.G609= | Silent (SNP) | VAF 33/290 reads (11%) | called by muse, mutect2, varscan2
- POLR3A | c.3651G>A p.Q1217= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- RPL37A | c.279G>A p.*93= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- RTL9 | c.720A>G p.E240= | Silent (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.78A>T p.P26= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV64225914; called by muse, mutect2, varscan2
- TLE4 | c.633C>T p.A211= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV54638520; called by muse, mutect2
- UGGT1 | c.2055C>A p.I685= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- UGT1A5 | c.219C>T p.N73= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV59394395; called by muse, mutect2, varscan2
- ZNF705A | c.435C>T p.V145= | Silent (SNP) | VAF 9/245 reads (4%) | called by muse, mutect2
- CCDC30 | c.385-6205C>T | Intron (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- DCHS2 | n.3989C>T | RNA (SNP) | VAF 20/56 reads (36%) | catalogued as COSV61776538; called by muse, mutect2, varscan2
- FAIM | c.-23+1875G>C | Intron (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-137C>T | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580920 A>C | 3'Flank (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
